MMRF case MMRF_1866 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/79e81621-6ba7-4642-989e-0db179ef84fc

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.5 years (21,354 days); ISS stage: I; Days to last known disease status: 1,009 days (2.8 years); Days to last follow up: 1,009 days (2.8 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 13 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 235 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 33 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days; Days to treatment end: 57 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 65 days; Days to treatment end: 78 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 85 days; Days to treatment end: 96 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 104 days; Days to treatment end: 985 days (2.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 38 (ECOG 0): M Protein 3.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.75 mg/dL; Immunoglobulin G 5.04 g/L; Immunoglobulin A 53.4 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 2.04 µg/mL; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 9.7 g/dL; Glucose 5.12 mmol/L.
- Day 147 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.22 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 1.77 g/L; Immunoglobulin M 0.16 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 317 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 5.12 mmol/L.
- Day 225 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 1.68 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 4.9 mmol/L.
- Day 315 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 2.04 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 5.12 mmol/L.
- Day 387 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 2.27 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 7.4 g/dL; Glucose 6.66 mmol/L.
- Day 463 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 2.38 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1.33 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 5.94 mmol/L.
- Day 555 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 3.13 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 9.11 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.45 mmol/L; Albumin 47 g/L; Total Protein 7.7 g/dL; Glucose 4.84 mmol/L.
- Day 652 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 3.57 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 8.99 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.45 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 5.5 mmol/L.
- Day 742 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 3.63 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 5.61 mmol/L.
- Day 856: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.69 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 13.7 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 6.12 µg/mL; Hemoglobin 6.01 mmol/L; Leukocytes 5.42 ×10⁹/L; Absolute Neutrophil 4.14 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.3 mmol/L; Glucose 8.2 mmol/L.
- Day 942 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.89 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 4.22 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.35 µg/mL; Hemoglobin 8.87 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 5.61 mmol/L.
- Day 1,009 (ECOG 0): Hemoglobin 8.43 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 220 ×10⁹/L.

Other clinical attributes
- Day 38: Weight: 61 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1866_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 38 days.
- Sample MMRF_1866_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 38 days.
